Somatic mutation profile of tumor specimen TCGA-ED-A97K-01A (aliquot TCGA-ED-A97K-01A-21D-A382-10) from TCGA case TCGA-ED-A97K, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Combined hepatocellular carcinoma and cholangiocarcinoma; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 55.0 years (20,073 days).
Specimen TCGA-ED-A97K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab3dac71-70c8-47e6-8cef-94fa0f6b63e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ED-A97K-10A (Blood Derived Normal), aliquot TCGA-ED-A97K-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/542f6b57-7be1-4c08-9227-2c747db6308f

The open-access MAF lists 52 somatic variants for this specimen: 43 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 8, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 2, Splice Region 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFAP1 | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100632104, COSV61797913; called by muse, mutect2, varscan2
- ARSK | c.702G>T p.V234= | Splice Region (SNP) | VAF 55/341 reads (16%) | catalogued as COSV101187577; called by muse, mutect2, varscan2
- ATP2B1 | c.1424A>C p.D475A | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99666104; called by muse, mutect2, varscan2
- BRINP2 | c.2053G>T p.V685F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV64176508; called by muse, mutect2, varscan2
- C14orf39 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100408076; called by muse, mutect2
- CDK5RAP1 | c.863A>G p.K288R | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1339486441, COSV100212273; called by muse, mutect2, varscan2
- COL13A1 | c.944G>A p.G315D (on ENST00000398978 / NM_001130103.2; = p.G258D on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768307635, COSV100637757; called by muse, mutect2, varscan2
- CPS1 | c.2294G>A p.S765N | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1356112836, COSV99243993; called by muse, mutect2, varscan2
- CSMD1 | c.5851C>T p.R1951C (on ENST00000520002; = p.R1950C on NM_033225.6) | Missense Mutation (SNP) | VAF 86/307 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1285112102, COSV100153230; called by muse, mutect2, varscan2
- CSMD1 | c.3230G>A p.R1077H (on ENST00000520002; = p.R1076H on NM_033225.6) | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748686121, COSV59302829; called by muse, mutect2, varscan2
- DNAH3 | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1221722019, COSV54526370, COSV99770342; called by muse, mutect2, varscan2
- DYNC1I1 | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.375); catalogued as COSV100269183; called by muse, mutect2, varscan2
- FANCM | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV99361156; called by muse, mutect2, varscan2
- FOXP1 | c.954A>T p.E318D | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV100562310; called by muse, mutect2, varscan2
- IGDCC4 | c.2613dup p.T872Hfs*22 | Frame Shift Ins (INS) | VAF 16/70 reads (23%) | catalogued as rs761621429; called by mutect2, varscan2
- INSIG2 | c.653T>A p.I218N | Missense Mutation (SNP) | VAF 87/538 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99830651; called by muse, mutect2, varscan2
- KCNN2 | c.628A>T p.T210S (on ENST00000264773; = p.T422S on NM_021614.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.629); catalogued as COSV99300645; called by muse, mutect2, varscan2
- KEL | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs771907965, COSV62335634; called by muse, mutect2, varscan2
- LCE3D | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs199832759, COSV100909873; called by muse, mutect2, varscan2
- LEFTY1 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1033970449, COSV99686626; called by muse, mutect2, varscan2
- LONRF1 | c.2240T>C p.V747A | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV101238259; called by muse, mutect2, varscan2
- LRIG3 | c.2785A>G p.M929V | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs758620273, COSV100292816, COSV57871375; called by muse, mutect2, varscan2
- MFAP5 | c.248-2A>C p.X83_splice | Splice Site (SNP) | VAF 9/120 reads (8%) | catalogued as COSV100848188; called by muse, mutect2
- OR8G1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as COSV100422644; called by muse, mutect2, varscan2
- PAGR1 | c.313T>A p.W105R | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100232785; called by muse, mutect2, varscan2
- PCDHGB2 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.029); catalogued as rs765885822, COSV53995660; called by muse, mutect2, varscan2
- PPP1R13B | c.964dup p.I322Nfs*64 | Frame Shift Ins (INS) | VAF 24/71 reads (34%) | catalogued as rs1223655873; called by mutect2, varscan2
- PRKCA | c.174G>C p.W58C | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99436062; called by muse, mutect2
- PTPN4 | c.1873G>T p.E625* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as COSV99751268; called by muse, mutect2, varscan2
- RASSF2 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs778467935, COSV101040914; called by muse, mutect2, varscan2
- SLC24A3 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100042894; called by muse, mutect2, varscan2
- SLC35F2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.41); catalogued as COSV99758856; called by muse, mutect2
- SLC36A3 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as rs758913228, COSV58855938; called by muse, mutect2, varscan2
- SLIT1 | c.3411G>T p.Q1137H | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV56589662, COSV99822409; called by muse, mutect2, varscan2
- SLITRK4 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.617); catalogued as COSV100567511; called by muse, mutect2, varscan2
- THRSP | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as rs147579530, COSV55246437; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1397T>G p.L466R | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV99162998; called by muse, mutect2, varscan2
- UGT1A8 | c.371G>T p.C124F | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV65080862; called by muse, mutect2, varscan2
- ZBTB45 | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99564603; called by muse, mutect2, varscan2
- ZFP57 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as rs1452510913, COSV100971960; called by muse, mutect2, varscan2
- KLF5 | c.1250_1254del p.S417* | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- NF1 | c.4436del p.F1479Sfs*4 (on ENST00000358273 / NM_001042492.3; = p.F1458Sfs*4 on NM_000267.3) | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- TGFBR2 | c.834del p.Y281Mfs*19 | Frame Shift Del (DEL) | VAF 61/168 reads (36%) | called by mutect2, pindel, varscan2
- CACNA1D | c.3981G>A p.V1327= (on ENST00000350061 / NM_001128840.3; = p.V1347= on NM_000720.4) | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99859273; called by muse, mutect2, varscan2
- CMTR1 | c.93C>T p.S31= | Silent (SNP) | VAF 38/170 reads (22%) | catalogued as rs971998102, COSV100990935; called by muse, mutect2, varscan2
- FAT4 | c.7962C>T p.Y2654= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as rs546465658, COSV58714441; called by muse, mutect2, varscan2
- NCKAP5 | c.2868C>T p.S956= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as rs746101038, COSV100491506; called by muse, mutect2, varscan2
- NRXN1 | c.660C>T p.G220= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV68002608, COSV68038322; called by muse, mutect2, varscan2
- PRICKLE1 | c.1488G>A p.R496= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV100454218; called by muse, mutect2, varscan2
- USP11 | c.2223G>A p.P741= (on ENST00000218348; = p.P698= on NM_001371072.1) | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs769936095, COSV99511152; called by muse, mutect2, varscan2
- ZFP2 | c.1113G>T p.V371= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as rs879000777, COSV63725668; called by muse, mutect2, varscan2
- KRAS | c.*56G>A | 3'UTR (SNP) | VAF 48/136 reads (35%) | catalogued as COSV99789374; called by muse, mutect2, varscan2
